Somatic mutation profile of tumor specimen TCGA-VS-A8QF-01A (aliquot TCGA-VS-A8QF-01A-21D-A37N-09) from TCGA case TCGA-VS-A8QF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 42.1 years (15,374 days).
Specimen TCGA-VS-A8QF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0816301c-7d21-4b5a-b807-a0b290330091.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A8QF-10A (Blood Derived Normal), aliquot TCGA-VS-A8QF-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b95218bb-2cb2-4d09-a1ff-5e34aeaba7e1

The open-access MAF lists 117 somatic variants for this specimen: 88 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 27, Nonsense Mutation 8, Splice Region 2, Translation Start Site 1, Frame Shift Del 1, RNA 1, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.10486G>C p.E3496Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100001563; called by muse, mutect2, varscan2
- AP1S3 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775010779, COSV57509417; called by muse, mutect2, varscan2
- ASPM | c.1911G>C p.K637N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV99660332; called by muse, mutect2, varscan2
- ATG2A | c.5180A>G p.Y1727C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101034331; called by muse, mutect2, varscan2
- B3GALT2 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs894908940, COSV100813593, COSV66464464; called by muse, mutect2, varscan2
- BMI1 | c.371T>G p.I124S | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV100936397; called by muse, mutect2, varscan2
- BMPR2 | c.2294C>G p.S765* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | catalogued as COSV101001484, COSV65813147; called by muse, mutect2
- CCDC190 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100905827; called by muse, mutect2, varscan2
- COMMD8 | c.440T>G p.V147G | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV101055697; called by muse, mutect2, varscan2
- CPAMD8 | c.1553A>G p.Y518C (on ENST00000651564; = p.Y471C on NM_015692.5) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.525); catalogued as COSV99359367; called by muse, mutect2, varscan2
- CPT1A | c.597C>G p.F199L | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs772640633, COSV55752556, COSV99681136; called by muse, mutect2
- CRB1 | c.3283G>T p.G1095W | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66330238; called by muse, mutect2, varscan2
- CSMD3 | c.5755G>A p.E1919K (on ENST00000297405 / NM_001363185.1; = p.E1815K on NM_052900.3) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0.062); catalogued as COSV99833844; called by muse, mutect2, varscan2
- DIAPH2 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100232716, COSV61281668; called by muse, mutect2
- DOK4 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1422790855, COSV99538313; called by muse, mutect2, varscan2
- DYNC2H1 | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100518518; called by muse, mutect2
- EIF4B | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.973); catalogued as rs1375478321, COSV50404869; called by muse, mutect2, varscan2
- ELAVL4 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV63914167; called by muse, mutect2, varscan2
- ERBB3 | c.2782G>C p.E928Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57252926, COSV99916817; called by muse, mutect2, varscan2
- FAT4 | c.9046G>T p.G3016* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100628099; called by mutect2, varscan2
- FN1 | c.5695G>A p.A1899T | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.809); catalogued as rs573992192, COSV60547894; called by muse, mutect2, varscan2
- GNAL | c.307C>G p.P103A (on ENST00000269162 / NM_001142339.3; = p.P180A on NM_182978.4) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as COSV99303489; called by mutect2, varscan2
- GPC5 | c.211A>G p.R71G | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV100993935; called by muse, mutect2, varscan2
- GRHL1 | c.776C>G p.S259* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100257807; called by muse, mutect2, varscan2
- IMMT | c.2208G>C p.Q736H | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781769634, COSV99606319; called by muse, mutect2, varscan2
- IREB2 | c.365C>G p.T122R | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as COSV99359370; called by muse, mutect2
- KRT14 | c.1418G>C p.*473Sext*49 | Nonstop Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99391016; called by muse, mutect2, varscan2
- LAMA4 | c.2006G>C p.S669T (on ENST00000230538 / NM_001105206.3; = p.S662T on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100038341, COSV57902829; called by muse, mutect2, varscan2
- LENG8 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.272); catalogued as COSV100457493; called by muse, mutect2, varscan2
- LIMCH1 | c.165C>T p.C55= | Splice Region (SNP) | VAF 14/65 reads (22%) | catalogued as rs371065654; called by muse, mutect2, varscan2
- LMX1B | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as CD042601, CM012785, COSV100827048; called by mutect2, varscan2
- LRP1B | c.5103C>G p.H1701Q | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV101256621; called by muse, mutect2, varscan2
- LRRC27 | c.156G>C p.L52F | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59810373, COSV59813073; called by muse, mutect2, varscan2
- MCOLN1 | c.907G>T p.V303L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV99900596; called by mutect2, varscan2
- MCOLN3 | c.1637C>G p.S546C | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1211637461, COSV100352741, COSV62013369, COSV62014593; called by muse, mutect2
- MEI1 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55903172; called by muse, mutect2, varscan2
- MUC5B | c.7928G>C p.R2643T | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs369687151, COSV101500304; called by muse, mutect2, varscan2
- MYO3A | c.3920C>T p.T1307I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.035); catalogued as rs1020182100, COSV99779604; called by muse, mutect2, varscan2
- MYOM1 | c.2118A>C p.K706N | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99866615; called by muse, mutect2
- NEU1 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99998906; called by muse, mutect2, varscan2
- PABPC3 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as COSV55806104, COSV99879487; called by muse, mutect2, varscan2
- PDZD2 | c.5801G>A p.R1934Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs1329190782, COSV56862842; called by muse, mutect2, varscan2
- PHF12 | c.72C>G p.I24M | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV99255761; called by muse, mutect2, varscan2
- PITPNA | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV100541480; called by muse, mutect2, varscan2
- PLD1 | c.379C>T p.H127Y | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100578112; called by muse, mutect2, varscan2
- PRICKLE1 | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100566352; called by muse, mutect2, varscan2
- RACK1 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100958715; called by muse, mutect2, varscan2
- RAD51C | c.1023C>G p.I341M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100506961; called by muse, mutect2, varscan2
- RAE1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64797745; called by muse, mutect2
- REV3L | c.4717C>T p.R1573W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as rs576113461, COSV100725160; called by mutect2, varscan2
- RIN3 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs148243669; called by muse, mutect2, varscan2
- RYR2 | c.3631C>G p.Q1211E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV100770034; called by muse, mutect2, varscan2
- SCAPER | c.3970G>A p.A1324T | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100238263; called by muse, mutect2, varscan2
- SDCCAG8 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100654231; called by muse, mutect2, varscan2
- SLC12A1 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as rs373101131; called by muse, mutect2, varscan2
- SLC2A2 | c.407T>G p.L136* | Nonsense Mutation (SNP) | VAF 9/109 reads (8%) | catalogued as COSV100049322; called by muse, mutect2
- SMAP1 | c.815C>A p.A272E (on ENST00000370455 / NM_001044305.3; = p.A245E on NM_021940.5) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.216); catalogued as COSV100016927; called by muse, mutect2, varscan2
- STAM | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101092275; called by muse, mutect2, varscan2
- STAT5B | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs757544937, COSV53186147; called by muse, mutect2, varscan2
- TCEA1 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as rs776875502, COSV101124245; called by muse, mutect2, varscan2
- TIMM8A | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV58122634; called by muse, mutect2, varscan2
- TKT | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as rs1553679757, COSV99964920; called by muse, mutect2, varscan2
- TLCD3B | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755480627, COSV99662432; called by muse, mutect2, varscan2
- TMEM37 | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99191577; called by muse, mutect2, varscan2
- TOGARAM2 | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.75); catalogued as rs903461954, COSV101091109; called by muse, mutect2, varscan2
- TP53INP1 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV100711073; called by muse, mutect2, varscan2
- TPM2 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV100253235; called by muse, mutect2, varscan2
- TRANK1 | c.1687G>A p.V563M | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs373399207, COSV100082614; called by mutect2, varscan2
- TTN | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 5/88 reads (6%) | PolyPhen benign (0.049); catalogued as rs794729621, COSV60000521, COSV60050122; ClinVar: uncertain significance; called by muse, mutect2
- TUBB | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 12/87 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100013363; called by muse, mutect2, varscan2
- UBIAD1 | c.1003C>G p.L335V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100954880; called by muse, mutect2, varscan2
- UHRF1BP1L | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV99691560; called by muse, mutect2, varscan2
- USP21 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 6/75 reads (8%) | catalogued as COSV99237412; called by muse, mutect2
- UTP4 | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100076963, COSV100076978; called by muse, mutect2, varscan2
- VPS39 | c.2493G>A p.R831= (on ENST00000348544 / NM_001301138.2; = p.R820= on NM_015289.5) | Splice Region (SNP) | VAF 8/28 reads (29%) | catalogued as rs756254232, COSV100529183; called by muse, mutect2, varscan2
- VWA8 | c.5647G>A p.A1883T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV101022612; called by muse, mutect2, varscan2
- VWA8 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs1394413146, COSV99864072; called by muse, mutect2, varscan2
- VWC2L | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1004663043, COSV100435793; called by muse, mutect2, varscan2
- WDR64 | c.2972G>A p.R991Q | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs200180061; called by muse, mutect2, varscan2
- YEATS2 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as COSV100527784; called by muse, mutect2, varscan2
- ZCCHC8 | c.1082T>A p.L361H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV100288658; called by muse, mutect2
- ZFPM2 | c.3272C>T p.S1091L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs746420683, COSV101023216; called by muse, mutect2
- ZNF226 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1244046497, COSV100335125; called by muse, mutect2, varscan2
- ZNF329 | c.970T>C p.F324L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100798736; called by muse, mutect2, varscan2
- ZNF429 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100641891; called by muse, mutect2, varscan2
- ZNF613 | c.859T>A p.S287T (on ENST00000293471 / NM_001031721.4; = p.S251T on NM_024840.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV99522929; called by muse, mutect2, varscan2
- ZNF777 | c.1804T>C p.C602R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as COSV99925177; called by muse, mutect2
- STXBP1 | c.760del p.Y254Mfs*23 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- AC098582.1 | c.795C>T p.T265= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV99985588; called by muse, mutect2, varscan2
- AKR1C2 | c.489C>T p.I163= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as rs139670873, COSV66333147; called by muse, mutect2, varscan2
- AP1M2 | c.537C>T p.V179= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99140833; called by muse, mutect2, varscan2
- ARHGAP39 | c.3150C>T p.S1050= (on ENST00000276826 / NM_001308208.2; = p.S1081= on NM_025251.2) | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1400390245, COSV52774858, COSV99432505; called by muse, mutect2, varscan2
- BRINP3 | c.1614G>A p.K538= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV66531191; called by muse, mutect2, varscan2
- CACNA1E | c.3585C>T p.G1195= | Silent (SNP) | VAF 10/109 reads (9%) | catalogued as rs376133244; called by muse, mutect2, varscan2
- CBLN2 | c.318C>T p.S106= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs144009820, COSV99504374; called by muse, mutect2, varscan2
- CETP | c.315C>T p.N105= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs763194082, COSV52364355; called by muse, mutect2, varscan2
- ENKD1 | c.723G>A p.Q241= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99537675; called by muse, mutect2, varscan2
- FLG2 | c.1677T>C p.Y559= | Silent (SNP) | VAF 31/156 reads (20%) | catalogued as COSV101165853; called by muse, mutect2, varscan2
- FMR1 | c.1122G>A p.Q374= | Silent (SNP) | VAF 14/244 reads (6%) | catalogued as COSV99503277; called by muse, mutect2
- FOXA2 | c.1278G>A p.P426= (on ENST00000377115 / NM_153675.3; = p.P432= on NM_021784.5) | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs1304085938, COSV101008354; called by muse, mutect2, varscan2
- GRIA4 | c.2433G>C p.L811= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV56889494, COSV99231333; called by muse, mutect2, varscan2
- KIF26A | c.2307G>A p.T769= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs767204145, COSV100181089; called by muse, mutect2, varscan2
- MAGEB6 | c.510C>T p.A170= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs746794376, COSV66872259; called by muse, mutect2, varscan2
- NCKAP5 | c.1849C>T p.L617= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100491943; called by muse, mutect2, varscan2
- OR4C46 | c.729G>A p.T243= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as rs781550990; called by muse, mutect2, varscan2
- OR5H1 | c.135G>C p.L45= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV100641765; called by muse, mutect2
- OR5K2 | c.244T>C p.L82= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as COSV101415967; called by muse, mutect2, varscan2
- PCDH9 | c.1719T>C p.T573= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100120565; called by muse, mutect2, varscan2
- RAN | c.225G>A p.L75= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV99619746; called by muse, mutect2, varscan2
- RLBP1 | c.156G>T p.L52= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV99175317; called by muse, mutect2, varscan2
- SLC15A1 | c.1755C>A p.I585= | Silent (SNP) | VAF 43/56 reads (77%) | catalogued as COSV100919476; called by muse, mutect2, varscan2
- VPS35 | c.339A>T p.T113= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100140641; called by mutect2, varscan2
- ZCCHC8 | c.1083C>G p.L361= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100288655; called by muse, mutect2, varscan2
- ZNF746 | c.1479C>T p.G493= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100502468; called by muse, mutect2, varscan2
- ZSWIM4 | c.2667G>A p.S889= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1159519764, COSV99584862; called by muse, mutect2, varscan2
- EIF4A1 | c.514+139C>T | Intron (SNP) | VAF 10/17 reads (59%) | catalogued as rs766373704, COSV99548939; called by muse, mutect2, varscan2
- SNORD113-7 | n.20C>T | RNA (SNP) | VAF 9/32 reads (28%) | catalogued as rs755771583; called by muse, mutect2, varscan2
